Surgical pathology report (de-identified scan), TCGA case TCGA-S7-A7WQ, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site University Hospital Motol, specimen TCGA-S7-A7WQ-01A (Primary Tumor).

[page 1 of 2]
Gross:

Right adrenal gland with tumor (weight 12 g, 40x30x20). On cut, grey-brown tumor with smooth surface and fibrous capsule.

Micro:

Solidly and alveolarly shaped pheochromocytoma with focal fresh hemorrhages. It consists partially from polygonal cells and partially from spindle cells. In surrounding parts, small adrenal cortex remnants are present. Adrenal cortex proliferate was found in the capsule sporadically. From the cytologic point of view, the tumor is polymorphic with present hyperchromatic nuclei somewhere, this finding is similar to the left-sided tumor. Prominent is focal dense infiltration by plasmatic cells, staining for kappa and lambda light chains is positive in variable, but polyclonal ratio.

Sustentacular cells (S100) are present in better differentiated tumor parts, in central diffusely growing parts are missed.

MIB-1 2-3% of tumor nuclei positive.

Staining for chromogranin is positive in cytoplasm of large tumor cells of the nodule, negative are adrenal cortex remnants and periadrenal adipose tissue with Feyrter's metaplasia. Positive stainin is also present in cytoplasm of smaller cells behind the adrenal capsule, which is possibly peripherally caught extracapsular tumor proliferation in adipose tissue. No angioinvasion was found.

PASS:

Large nests or diffuse growth (>10% of tumor volume) 2

Central (middle of large nests) or confluent tumor necrosis

High cellularity

Cellular monotony

Tumor cell spindling (even if focal) 2

Mitotic figures >3/10 HPF

Atypical mitotic figure(s)

ICD-O-3

Pheochromocytoma, malignant
870013

Site @ Adrenal gland
C74.9

10/9/13

[page 2 of 2]
Extension into adipose tissue 2

Vascular invasion

Capsular invasion 1

Profound nuclear pleomorphism 1

Nuclear hyperchromasia 1

Total 8

Procurement date:

Confirmation date:

Source: NCI Genomic Data Commons file 94abaf3a-b5b3-4efe-bf5f-d5c296ef3118 (TCGA-S7-A7WQ.D2A0DBEC-05DB-44FD-B005-C332466D12D4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).